Somatic mutation profile of tumor specimen TCGA-B0-4811-01A (aliquot TCGA-B0-4811-01A-01D-1501-10) from TCGA case TCGA-B0-4811, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 48.7 years (17,792 days).
Specimen TCGA-B0-4811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72ca2f25-1baf-4513-b0ae-332c90c40f13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4811-11A (Solid Tissue Normal), aliquot TCGA-B0-4811-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fa6a31a-2ab9-430a-82d5-33473e55b5a1

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 61, Silent 25, Frame Shift Del 7, Splice Site 4, Frame Shift Ins 2, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as COSV55586273; called by muse, mutect2, varscan2
- AC008397.2 | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028070498, COSV53205122; called by muse, mutect2, varscan2
- ADAMTSL2 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV63203383; called by muse, mutect2
- ADCY3 | c.2303T>A p.L768Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV53164876; called by muse, mutect2, varscan2
- ALPK3 | c.4525del p.R1509Gfs*72 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV51933161; called by mutect2, pindel, varscan2
- ANGPT4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV67920793; called by muse, mutect2, varscan2
- ASAP1 | c.1524G>C p.K508N | Missense Mutation (SNP) | VAF 108/444 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV63045004; called by muse, varscan2
- BAZ2B | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 375/1061 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54274946; called by muse, mutect2, varscan2
- CALD1 | c.884T>G p.I295S | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as COSV62645438; called by muse, mutect2, varscan2
- CDH8 | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV54851171; called by muse, mutect2
- CKAP2L | c.1602+1G>T p.X534_splice | Splice Site (SNP) | VAF 256/708 reads (36%) | catalogued as COSV56695817; called by muse, mutect2, varscan2
- CLCN1 | c.2824del p.L942Wfs*6 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV58374080; called by mutect2, pindel, varscan2
- CSMD3 | c.6700T>G p.F2234V (on ENST00000297405 / NM_001363185.1; = p.F2130V on NM_052900.3) | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV52113593; called by muse, mutect2, varscan2
- DCSTAMP | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52576425; called by muse, mutect2, varscan2
- DYNC2H1 | c.6811G>C p.G2271R | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as COSV62087603; called by muse, mutect2
- EP300 | c.6022T>C p.S2008P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54327558; called by muse, mutect2, varscan2
- ESPL1 | c.5729T>C p.L1910P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54475339; called by muse, mutect2, varscan2
- ESRP2 | c.1763C>G p.T588S (on ENST00000565858 / NM_001365264.1; = p.T578S on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52172214; called by muse, mutect2, varscan2
- EXOC3L4 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV101197728; called by muse, mutect2, varscan2
- GATAD2B | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64083355; called by muse, mutect2, varscan2
- GPR83 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV54717711; called by muse, mutect2, varscan2
- GREB1 | c.4427T>A p.M1476K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV52181803; called by muse, mutect2, varscan2
- GZF1 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57634992; called by muse, mutect2, varscan2
- IL2RB | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.874); catalogued as rs371340355; called by muse, mutect2, varscan2
- IL6ST | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61139889; called by muse, mutect2
- INSC | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as COSV65409053; called by muse, mutect2, varscan2
- IPO13 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.078); catalogued as rs772498559, COSV54836365; called by muse, mutect2, varscan2
- ITGB1 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56479479; called by muse, mutect2, varscan2
- JPT2 | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50188532; called by muse, mutect2, varscan2
- KCNH7 | c.2907A>C p.E969D | Missense Mutation (SNP) | VAF 194/515 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1261724871, COSV59787343; called by muse, mutect2, varscan2
- KMT2D | c.5749A>G p.S1917G | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56415486; called by muse, mutect2, varscan2
- LENG9 | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs373957553, COSV100002705, COSV56617597; called by muse, mutect2, varscan2
- MCM3AP | c.2959A>T p.N987Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52436702; called by muse, mutect2, varscan2
- MYH1 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs765204648, COSV56844350; called by muse, mutect2, varscan2
- NEK9 | c.2767A>G p.I923V | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV53129496; called by muse, mutect2, varscan2
- PABPC1 | c.687A>T p.K229N | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV59399005; called by muse, varscan2
- PARP10 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57296886; called by muse, mutect2, varscan2
- PDRG1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs1228778346, COSV52431047; called by muse, mutect2, varscan2
- PIK3R4 | c.1001A>T p.E334V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV63239329; called by muse, mutect2, varscan2
- PKN3 | c.2049-2A>C p.X683_splice | Splice Site (SNP) | VAF 18/114 reads (16%) | catalogued as COSV52575124; called by muse, mutect2
- PRPF8 | c.4628A>T p.N1543I | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59261097; called by muse, mutect2, varscan2
- PRR14 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV54910861; called by muse, mutect2, varscan2
- PSMA6 | c.77-1G>C p.X26_splice | Splice Site (SNP) | VAF 56/211 reads (27%) | catalogued as COSV54836569; called by muse, mutect2, varscan2
- QPRT | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV54879178, COSV54880056, COSV54880562; called by muse, mutect2, varscan2
- RAC3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.192); catalogued as COSV60710499; called by muse, mutect2, varscan2
- REV1 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV51482305; called by muse, mutect2, varscan2
- RNF25 | c.288-2A>G p.X96_splice | Splice Site (SNP) | VAF 23/83 reads (28%) | catalogued as COSV55306171; called by muse, mutect2
- SCTR | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50026998; called by muse, mutect2, varscan2
- SEPHS2 | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV72100713; called by muse, mutect2, varscan2
- SERPINB8 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as rs776727128, COSV54639167; called by muse, mutect2, varscan2
- SLC27A1 | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53095553; called by muse, mutect2, varscan2
- SLC2A14 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs140568143; called by muse, mutect2, varscan2
- SLC44A1 | c.1929T>A p.D643E | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58262503; called by muse, mutect2, varscan2
- SLC5A10 | c.351C>T p.I117= | Splice Region (SNP) | VAF 19/95 reads (20%) | catalogued as rs754960897, COSV58755664; called by muse, mutect2, varscan2
- TBC1D1 | c.1204A>T p.I402L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV54714836; called by muse, mutect2, varscan2
- TG | c.6694C>T p.P2232S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066753; called by muse, mutect2, varscan2
- TJP2 | c.2563A>G p.T855A | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55263159; called by muse, mutect2, varscan2
- TMUB2 | c.304C>A p.P102T (on ENST00000538716 / NM_001353177.2; = p.P82T on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV60228253; called by muse, mutect2, varscan2
- TREML1 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 89/368 reads (24%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.011); catalogued as COSV64191013; called by muse, mutect2, varscan2
- TVP23A | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV51593103; called by muse, mutect2, varscan2
- UBR2 | c.4903G>A p.V1635M | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV65749011, COSV65751546; called by muse, mutect2
- UGT1A7 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 141/396 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs1476562728, COSV60832874, COSV60838872; called by muse, mutect2, varscan2
- USP37 | c.1544C>A p.P515Q | Missense Mutation (SNP) | VAF 196/605 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as COSV51441681; called by muse, mutect2, varscan2
- VMO1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs769635160, COSV54495854; called by muse, varscan2
- VPS13C | c.3447A>G p.I1149M (on ENST00000644861 / NM_020821.3; = p.I1106M on NM_017684.5) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51125140; called by muse, mutect2, varscan2
- ZNF256 | c.280A>C p.I94L | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV56596410; called by muse, mutect2
- ZNF496 | c.1708C>G p.R570G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54174157, COSV54174379; called by muse, mutect2, varscan2
- ZNF621 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV59457474; called by muse, mutect2, varscan2
- CCDC181 | c.49dup p.D17Gfs*2 | Frame Shift Ins (INS) | VAF 289/1142 reads (25%) | called by mutect2, pindel, varscan2
- GUF1 | c.664_665insAA p.I222Kfs*34 | Frame Shift Ins (INS) | VAF 40/258 reads (16%) | called by mutect2, pindel, varscan2
- IDI1 | c.466del p.S156Vfs*6 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- NUDT12 | c.638_640dup p.A213dup | In Frame Ins (INS) | VAF 62/253 reads (25%) | called by mutect2, pindel, varscan2
- PAPOLG | c.2013del p.F671Lfs*62 | Frame Shift Del (DEL) | VAF 205/586 reads (35%) | called by mutect2, pindel, varscan2
- PCDHB6 | c.64del p.W22Gfs*26 | Frame Shift Del (DEL) | VAF 218/743 reads (29%) | called by mutect2, pindel, varscan2
- SETD2 | c.5333del p.L1778Cfs*9 | Frame Shift Del (DEL) | VAF 72/157 reads (46%) | called by mutect2, pindel, varscan2
- ZNF799 | c.1890del p.F630Lfs*52 | Frame Shift Del (DEL) | VAF 96/314 reads (31%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.2352C>T p.H784= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV64210827; called by muse, mutect2, varscan2
- CAMTA2 | c.2043A>G p.E681= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV61833455; called by muse, mutect2, varscan2
- CMTR2 | c.1734A>T p.I578= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV57602664; called by muse, mutect2, varscan2
- COASY | c.525G>A p.R175= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55897703; called by muse, mutect2, varscan2
- COL12A1 | c.3528C>G p.T1176= | Silent (SNP) | VAF 154/462 reads (33%) | catalogued as COSV59390577, COSV59407843; called by muse, mutect2, varscan2
- DGKZ | c.369G>A p.Q123= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58985129; called by muse, varscan2
- DPF2 | c.795A>C p.G265= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as rs749275482, COSV52887994; called by muse, mutect2, varscan2
- EEF1D | c.63A>T p.A21= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV57817859; called by muse, mutect2, varscan2
- GRIN3A | c.612C>A p.G204= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV62451304, COSV62452600; called by muse, mutect2, varscan2
- KMT2D | c.5748C>G p.G1916= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56415502; called by muse, mutect2, varscan2
- LAMA5 | c.6597C>T p.S2199= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53354060; called by muse, mutect2, varscan2
- LMBR1L | c.906T>C p.A302= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57267050; called by muse, mutect2, varscan2
- MGAT5 | c.108G>A p.Q36= | Silent (SNP) | VAF 87/244 reads (36%) | catalogued as COSV56094237; called by muse, mutect2, varscan2
- MUC15 | c.867G>A p.P289= | Silent (SNP) | VAF 49/374 reads (13%) | catalogued as rs201499877, COSV55553022; called by muse, mutect2, varscan2
- NOTCH2 | c.2124C>T p.C708= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs781837919, COSV56683448; called by muse, mutect2, varscan2
- NR2C1 | c.1518A>G p.V506= | Silent (SNP) | VAF 104/401 reads (26%) | catalogued as COSV58008861; called by muse, mutect2, varscan2
- NR4A1 | c.270G>A p.S90= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs1340461519, COSV54480241; called by muse, mutect2, varscan2
- PABPC1 | c.708A>C p.V236= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as COSV59398993; called by muse, varscan2
- SEMA6D | c.2742G>A p.S914= (on ENST00000316364 / NM_153618.2; = p.S852= on NM_020858.2) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs765465054, COSV60373313; called by muse, mutect2, varscan2
- SLC35B2 | c.198G>A p.L66= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV51487904; called by muse, mutect2, varscan2
- TAF15 | c.129T>C p.D43= | Silent (SNP) | VAF 103/395 reads (26%) | called by muse, mutect2, varscan2
- TECRL | c.885T>C p.F295= | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as COSV67085759; called by muse, mutect2, varscan2
- TRIO | c.6066T>A p.I2022= | Silent (SNP) | VAF 14/294 reads (5%) | catalogued as COSV60078493; called by muse, mutect2
- ZNF232 | c.753T>C p.T251= | Silent (SNP) | VAF 72/269 reads (27%) | catalogued as COSV51502581; called by muse, mutect2, varscan2
- ZNF256 | c.282A>T p.I94= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as COSV56596395; called by muse, mutect2
